Somatic mutation profile of tumor specimen TCGA-AB-2849-03B (aliquot TCGA-AB-2849-03B-01W-0728-08) from TCGA case TCGA-AB-2849, project TCGA-LAML (Acute Myeloid Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia, minimal differentiation; Tissue or organ of origin: Bone marrow; Age at diagnosis: 39.8 years (14,520 days).
Specimen TCGA-AB-2849-03B: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 99899409-b68f-41cc-9b3d-e8b021ee64e3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AB-2849-11B (Solid Tissue Normal), aliquot TCGA-AB-2849-11B-01W-0729-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fedff9d3-10b0-4d18-82e8-9243bb9e8df8

The open-access MAF lists 28 somatic variants for this specimen: 22 protein-altering or splice-affecting, 6 silent.
By variant classification: Missense Mutation 16, Silent 6, Nonsense Mutation 2, Splice Region 2, Frame Shift Ins 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADGRG4 | c.1283T>A p.L428H | Missense Mutation (SNP) | VAF 358/495 reads (72%) | SIFT deleterious (0); PolyPhen possibly damaging (0.84); catalogued as COSV54948799; called by muse, mutect2, varscan2
- CDT1 | c.1183C>A p.P395T | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT tolerated (0.12); PolyPhen benign (0.009); catalogued as COSV56347252; called by muse, mutect2, varscan2
- CHMP3 | c.357G>T p.K119N | Missense Mutation (SNP) | VAF 10/190 reads (5%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.977); catalogued as COSV55688302; called by muse, mutect2
- DCTD | c.14C>T p.S5F | Missense Mutation (SNP) | VAF 64/237 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.1); catalogued as rs1164402011, COSV63866653; called by muse, mutect2, varscan2
- DOCK8 | c.5040_5041insT p.D1681* | Frame Shift Ins (INS) | VAF 52/184 reads (28%) | catalogued as COSV66617435; called by mutect2, pindel*, varscan2
- EPHX3 | c.913dup p.E305Gfs*98 | Frame Shift Ins (INS) | VAF 4/34 reads (12%) | catalogued as rs759392371; called by pindel, varscan2
- GBP1 | c.1518G>T p.L506F | Missense Mutation (SNP) | VAF 414/1266 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.768); catalogued as COSV65082546; called by muse, mutect2, varscan2
- KAT6B | c.1800C>G p.H600Q | Missense Mutation (SNP) | VAF 41/84 reads (49%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as COSV54741434; called by muse, mutect2, varscan2
- KDM3B | c.2813G>A p.R938H | Missense Mutation (SNP) | VAF 12/18 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58687612, COSV58694972; called by muse, varscan2
- MED21 | c.68T>C p.I23T | Missense Mutation (SNP) | VAF 83/198 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.105); catalogued as rs1327907485, COSV51460609; called by muse, mutect2, varscan2
- PLEKHG1 | c.412G>T p.D138Y | Missense Mutation (SNP) | VAF 6/79 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV100651524; called by muse, mutect2
- PRAMEF2 | c.737C>T p.T246M | Missense Mutation (SNP) | VAF 134/349 reads (38%) | SIFT tolerated (0.27); PolyPhen benign (0.006); catalogued as rs143792800; called by muse, mutect2, varscan2
- PRPF4B | c.2025T>C p.Y675= | Splice Region (SNP) | VAF 30/88 reads (34%) | catalogued as rs758029894, COSV61783204; called by muse, mutect2, varscan2
- RAB15 | c.327C>T p.Y109= (on ENST00000533601 / NM_001308154.2; = p.T153M on NM_198686.3) | Splice Region (SNP) | VAF 231/575 reads (40%) | catalogued as rs766813100, COSV50824101; called by muse, mutect2, varscan2
- RBFOX2 | c.227G>A p.R76Q | Missense Mutation (SNP) | VAF 24/194 reads (12%) | SIFT tolerated, low confidence (0.37); PolyPhen probably damaging (0.947); catalogued as rs562357805, COSV63857087; called by muse, mutect2, varscan2
- REV3L | c.4226C>A p.S1409* | Nonsense Mutation (SNP) | VAF 12/218 reads (6%) | catalogued as COSV62620297; called by muse, mutect2
- SNRNP200 | c.304T>C p.Y102H | Missense Mutation (SNP) | VAF 314/832 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60486994; called by muse, mutect2, varscan2
- SPEN | c.7503G>A p.W2501* | Nonsense Mutation (SNP) | VAF 161/420 reads (38%) | catalogued as COSV65357423; called by muse, mutect2, varscan2
- SUMO2 | c.278G>A p.G93D | Missense Mutation (SNP) | VAF 19/41 reads (46%) | SIFT deleterious (0.02); PolyPhen benign (0.209); catalogued as COSV58813093, COSV58813420; called by mutect2, varscan2
- THRAP3 | c.2168G>A p.R723H | Missense Mutation (SNP) | VAF 74/185 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.299); catalogued as rs375288205; called by muse, mutect2, varscan2
- TRIO | c.392G>A p.R131H | Missense Mutation (SNP) | VAF 113/271 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV60077180; called by muse, mutect2, varscan2
- ZPBP | c.914G>C p.G305A | Missense Mutation (SNP) | VAF 9/18 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50422362; called by muse, mutect2, varscan2
- DUOX1 | c.2613T>A p.I871= | Silent (SNP) | VAF 178/420 reads (42%) | catalogued as COSV58477093; called by muse, mutect2, varscan2
- MICALL1 | c.1761C>A p.G587= | Silent (SNP) | VAF 69/200 reads (35%) | catalogued as COSV53239222; called by muse, mutect2, varscan2
- MYF6 | c.630G>A p.S210= | Silent (SNP) | VAF 71/174 reads (41%) | catalogued as COSV57350576, COSV99952639; called by muse, mutect2, varscan2
- NAV2 | c.4560C>T p.P1520= (on ENST00000396087 / NM_001244963.2; = p.P1497= on NM_145117.5) | Silent (SNP) | VAF 10/29 reads (34%) | catalogued as COSV60656247; called by muse, mutect2, varscan2
- NLRC4 | c.105C>T p.R35= | Silent (SNP) | VAF 153/417 reads (37%) | catalogued as rs751915363, COSV61591224, COSV61594354; called by muse, mutect2, varscan2
- NRG3 | c.204C>T p.C68= | Silent (SNP) | VAF 15/39 reads (38%) | catalogued as COSV64543128; called by muse, mutect2, varscan2
